Somatic mutation profile of tumor specimen 0DM4XS from CCDI case PBBZVA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 20.7 years (7,574 days).
Specimen 0DM4XS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d6bf7a4-7f32-426d-a532-4340ad0d92e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM4X3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2750ff7a-c6ee-43c3-b231-bba95d2f75f9

The open-access MAF lists 67 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, 5'UTR 6, 3'UTR 5, In Frame Del 4, Frame Shift Del 3, Intron 2, Splice Site 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 129/302 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV64731793, COSV64731830, COSV64732212; called by muse, mutect2, varscan2
- TP53 | c.393_395del p.N131del | In Frame Del (DEL) | VAF 298/319 reads (93%) | hotspot (GDC flag); catalogued as rs879254214; called by pindel, varscan2
- ARFGEF3 | c.4463C>T p.T1488M | Missense Mutation (SNP) | VAF 189/295 reads (64%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.72); catalogued as rs749006587, COSV52459151, COSV52472964; called by muse, mutect2, varscan2
- ARHGEF9 | c.1454G>A p.G485D | Missense Mutation (SNP) | VAF 242/764 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV53643671; called by muse, mutect2, varscan2
- ARSB | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 204/463 reads (44%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as rs746972113, COSV53729190; called by muse, mutect2, varscan2
- CCDC39 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 149/354 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368439919; called by muse, mutect2, varscan2
- CNGA2 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 167/404 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61704707; called by muse, mutect2, varscan2
- ENTPD2 | c.1046_1048del p.F349del | In Frame Del (DEL) | VAF 138/354 reads (39%) | catalogued as rs774835653; called by pindel, varscan2
- ERAP2 | c.2576_2578del p.L859del | In Frame Del (DEL) | VAF 176/425 reads (41%) | catalogued as rs1461739050; called by mutect2, pindel, varscan2
- GCNA | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 120/1418 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs1443705799; called by muse, mutect2
- KIR2DL3 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 208/233 reads (89%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs199818198, COSV60898782; called by muse, mutect2, varscan2
- LRRC72 | c.793A>G p.T265A | Missense Mutation (SNP) | VAF 153/461 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs1295818344; called by muse, varscan2
- MMP8 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 132/143 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1208208995, COSV52634949; called by muse, mutect2, varscan2
- MUC12 | c.1826C>T p.T609M (on ENST00000379442; = p.T466M on NM_001164462.1) | Missense Mutation (SNP) | VAF 220/1666 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs748803963; called by muse, mutect2, varscan2
- N4BP2 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 171/411 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1128374; called by muse, mutect2, varscan2
- PCDHA3 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 17/603 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63544666; called by muse, mutect2
- PDPR | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 109/682 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.936); catalogued as rs755225545; called by muse, mutect2, varscan2
- PPP1R3F | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs1557118811; called by muse, mutect2, varscan2
- RAG1 | c.2143G>A p.V715M | Missense Mutation (SNP) | VAF 58/490 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1326444164, COSV55027422; called by muse, mutect2, varscan2
- RRP12 | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 117/303 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs761936629; called by muse, mutect2, varscan2
- SPTA1 | c.1677+1G>A p.X559_splice | Splice Site (SNP) | VAF 186/415 reads (45%) | catalogued as COSV63750239; called by muse, mutect2, varscan2
- ABCA12 | c.206C>A p.P69Q | Missense Mutation (SNP) | VAF 268/531 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ANO7 | c.2648_2652del p.V883Afs*7 (on ENST00000274979; = p.V829Afs*7 on NM_001370694.2) | Frame Shift Del (DEL) | VAF 119/370 reads (32%) | called by mutect2, pindel, varscan2
- ATRX | c.4153C>T p.Q1385* | Nonsense Mutation (SNP) | VAF 124/402 reads (31%) | called by muse, mutect2, varscan2
- AXDND1 | c.2734G>C p.G912R | Missense Mutation (SNP) | VAF 210/437 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- BCOR | c.1432_1433del p.S478Rfs*3 | Frame Shift Del (DEL) | VAF 164/560 reads (29%) | called by pindel, varscan2
- CENPB | c.863_864del p.E288Vfs*98 | Frame Shift Del (DEL) | VAF 78/236 reads (33%) | called by pindel, varscan2
- DEPDC1B | c.327_329del p.S110del | In Frame Del (DEL) | VAF 96/298 reads (32%) | called by pindel, varscan2
- E2F7 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 59/499 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESRRA | c.801G>C p.E267D | Missense Mutation (SNP) | VAF 151/335 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- EYS | c.3620G>T p.C1207F | Missense Mutation (SNP) | VAF 194/446 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, varscan2
- LRFN2 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 260/708 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- LY86 | c.391T>A p.F131I | Missense Mutation (SNP) | VAF 162/511 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAS1L | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 233/389 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMC4 | c.2019+1G>A p.X673_splice | Splice Site (SNP) | VAF 116/282 reads (41%) | called by muse, mutect2, varscan2
- SPATA31A3 | c.3575C>A p.T1192K | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SYK | c.1829C>T p.T610I | Missense Mutation (SNP) | VAF 120/279 reads (43%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF10 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 138/265 reads (52%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TRDN | c.1663G>T p.G555C | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CASK | c.1332C>T p.H444= | Silent (SNP) | VAF 74/417 reads (18%) | catalogued as rs753172505; called by muse, mutect2, varscan2
- CRACD | c.2658G>A p.A886= | Silent (SNP) | VAF 153/300 reads (51%) | catalogued as rs1317053467, COSV99949959; called by muse, mutect2, varscan2
- FGA | c.2412G>A p.G804= | Silent (SNP) | VAF 11/278 reads (4%) | called by muse, mutect2
- HMCN1 | c.6420C>T p.D2140= | Silent (SNP) | VAF 158/375 reads (42%) | catalogued as rs1413433754, COSV54893978, COSV54936825; called by muse, mutect2, varscan2
- KLHL31 | c.1302C>T p.A434= | Silent (SNP) | VAF 60/275 reads (22%) | called by muse, mutect2, varscan2
- MED9 | c.252C>T p.H84= | Silent (SNP) | VAF 97/231 reads (42%) | called by muse, mutect2, varscan2
- NECTIN4 | c.483G>A p.E161= | Silent (SNP) | VAF 130/342 reads (38%) | catalogued as rs1384378905; called by muse, mutect2, varscan2
- NUDT10 | c.87C>T p.R29= | Silent (SNP) | VAF 116/662 reads (18%) | catalogued as rs782132884, COSV62854323; called by muse, varscan2
- PCNT | c.6438C>T p.A2146= | Silent (SNP) | VAF 147/288 reads (51%) | called by muse, mutect2, varscan2
- RDH5 | c.45G>A p.L15= | Silent (SNP) | VAF 123/305 reads (40%) | catalogued as rs1421902393, COSV57676395; called by muse, mutect2, varscan2
- SLC7A13 | c.1152G>A p.Q384= | Silent (SNP) | VAF 119/357 reads (33%) | called by muse, mutect2, varscan2
- STAB2 | c.5856G>A p.K1952= | Silent (SNP) | VAF 179/394 reads (45%) | catalogued as rs780207195; called by muse, mutect2, varscan2
- TARBP1 | c.30C>G p.L10= | Silent (SNP) | VAF 131/279 reads (47%) | catalogued as rs758550646; called by muse, mutect2, varscan2
- TASOR | c.3840C>A p.V1280= (on ENST00000355628 / NM_001365636.2; = p.V904= on NM_015224.3) | Silent (SNP) | VAF 82/210 reads (39%) | catalogued as rs1397704698; called by muse, mutect2, varscan2
- CD96 | c.*44A>T | 3'UTR (SNP) | VAF 27/137 reads (20%) | called by muse, mutect2, varscan2
- CYB5RL | c.*82G>A | 3'UTR (SNP) | VAF 30/69 reads (43%) | catalogued as rs745637580; called by muse, mutect2, varscan2
- DNAH14 | c.5584+5626G>A | Intron (SNP) | VAF 165/381 reads (43%) | catalogued as rs528476887; called by muse, mutect2, varscan2
- FCSK | c.-15C>G | 5'UTR (SNP) | VAF 26/200 reads (13%) | catalogued as COSV55367402; called by muse, mutect2, varscan2
- GOLGA6L3 | n.855G>A | RNA (SNP) | VAF 6/26 reads (23%) | catalogued as rs201833000; called by muse, varscan2
- HMSD | c.*21A>G | 3'UTR (SNP) | VAF 76/188 reads (40%) | called by muse, mutect2, varscan2
- KLF17 | c.-55G>A | 5'UTR (SNP) | VAF 32/84 reads (38%) | catalogued as rs1407218028, COSV64856639; called by muse, mutect2, varscan2
- MDP1 | c.-73G>A | 5'UTR (SNP) | VAF 58/119 reads (49%) | called by muse, mutect2, varscan2
- MTCH1 | c.-40C>T | 5'UTR (SNP) | VAF 61/90 reads (68%) | catalogued as rs529296656; called by muse, mutect2, varscan2
- OR56B1 | c.-65G>A | 5'UTR (SNP) | VAF 21/34 reads (62%) | called by muse, mutect2, varscan2
- PLD5 | c.-68C>T | 5'UTR (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
- POLR3GL | c.382+21G>T | Intron (SNP) | VAF 134/273 reads (49%) | called by muse, mutect2, varscan2
- RPL28 | c.*3191_*3192del | 3'UTR (DEL) | VAF 32/56 reads (57%) | called by pindel, varscan2
- TUBAL3 | c.*39T>A | 3'UTR (SNP) | VAF 42/395 reads (11%) | called by muse, mutect2, varscan2
